Surgical pathology report (de-identified scan), TCGA case TCGA-56-5897, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-5897-01A (Primary Tumor).

[page 1 of 2]
Collection Date: [REDACTED]
Hospital of Origin:
Copy to:

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Lung, right upper lobe, excision:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: 2/3 - moderately differentiated.
3. Tumor site: Right upper lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 2.2 x 2.0 x 2.0 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Not identified.
8. Tumor extension: Tumor remains isolated within lung parenchyma.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 4.7 cm.
2. Tumor distance from parenchymal (stapled) margin: 5.0 cm.
3. Tumor distance from pleural surface: 0.3 cm.

Lymph Node Status:

1. Total number of lymph nodes received: 1.
2. Total number of lymph nodes containing metastatic carcinoma: 0.

Other:

1. pTNM stage: pT1b N0
- B. Level 7 lymph node, excision:
One lymph node, without evidence of metastatic disease.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] male with right lung mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right upper lobe
- B. Level 7 lymph node

CODES:

[page 2 of 2]
PROCEDURAL DEMOGRAPHICS:

Date of Procedure: [REDACTED]

Accession Date/Time: [REDACTED]

GROSS DESCRIPTION:

A. The first container A is labeled [REDACTED] right upper lobe. The specimen consists of a lung lobectomy specimen measuring 11.0 x 11.0 x 6.5 cm and weighs 211 grams. The pleural surface is gray to brown tan with hemorrhage. The pleura has been inked. Sectioning reveals a circumscribed gray tan to yellow tan slightly anthracotic mass measuring 2.2 x 2.0 x 2.0 cm that is 0.3 cm from the pleural margin, 4.7 cm from the bronchial margin of resection and is within 5.0 cm of the closest staple line. On sectioning through the mass there is focal areas of purulent material exuding from the mass. The surrounding lung tissue is red to orange tan spongy with hemorrhage. Within the peribronchial soft tissue there is a brown tan anthracotic nodule consistent with a lymph node measuring 0.4 cm. Received with the specimen are two cassettes, one green and one yellow, labeled [REDACTED]. Representative sections are submitted in cassettes as follows: mass--1 to 4; bronchial and vascular margin--5; surrounding lung--6; shave section from stapled edge--7; peribronchial lymph node--8.

B. The second container B is labeled [REDACTED] level 7 lymph node. The specimen consists of a brown tan anthracotic nodule consistent with a lymph node measuring 0.5 x 0.5 x 0.2 cm. The specimen is entirely submitted in a single cassette.

Source: NCI Genomic Data Commons file df6d941d-3af5-43fb-a3fc-e9da191f3992 (TCGA-56-5897.8EFC19C8-AB28-4FF9-A2C6-4CAEFE60D0F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).